Somatic mutation profile of tumor specimen TARGET-20-PASBPW-09A (aliquot TARGET-20-PASBPW-09A-01D) from TARGET case TARGET-20-PASBPW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,215 days).
Specimen TARGET-20-PASBPW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a120559-ee41-4848-95d9-9480d5694b94.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASBPW-14A (Bone Marrow Normal), aliquot TARGET-20-PASBPW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5d3eb03-966e-4c93-b3b9-10a0a03eac49

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>G p.N822K | Missense Mutation (SNP) | VAF 18/236 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NCOR1 | c.6401dup p.S2136Ifs*25 | Frame Shift Ins (INS) | VAF 62/188 reads (33%) | called by mutect2, pindel, varscan2
